Surgical pathology report (de-identified scan), TCGA case TCGA-68-7757, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-7757-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]
[REDACTED]

SPECIMEN SUBMITTED:

Part A: 7
Part B: R4
Part C: 4L
Part D: R2
Part E: L2
Part F: LEVEL 5
Part G: LEFT UPPER LOBE
Part H: LEVEL 4
Part I: LEVEL 7
Part J: LEVEL 10
Part K: LEVEL 11

Final Diagnosis

1. Lymph nodes, #7, R44L R2 L2 Level 5 Level 4 Level 7,, Level 10 Level 11excision (A-F, H-K) - Lymph nodes; negative for malignancy.
7. Left upper lobe, lobectomy (G) - Invasive moderately differentiated squamous cell carcinoma (see comment).
- Interstitial scarring fibrosis.
- Centrilobular emphysema.

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

Tumor Location: Left upper lobe

Tumor Size: 2.5 x 2.6 x 2.5 cm

Vascular Invasion: Not identified

Lymphatic Invasion: Not identified

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): Stage IA (pT1b, N0, MX)

Additional comments: Immunohistochemical stains for cytokeratin CAM 5.2, TTF-1, and p63 were used in the evaluation of this tumor. The tumor cells stained positively for CAM 5.2 and p63, and were negative for TTF-1. The fibrotic stroma within the tumor is negative for CAM 5.2. This supports the diagnosis of squamous cell carcinoma.

The squamous cell carcinoma is in association with a localized area of interstitial fibrosis with hemosiderosis and foci of organizing and recanalizing vascular thrombi. The fibrosis is localized to the subpleural region, consistent with a pulmonary scar, that could be due to previous trauma or surgical procedure in this area (patient's history of prior cardiac surgery). In addition, the vascular changes present suggest that an old scarring pulmonary infarct could be another possible etiology of the localized interstitial fibrosis. Correlation with clinical and radiologic findings is needed.

Procedure: ADDENDUM

Status: Signed Out

Text:

Intraoperative Diagnosis:

- A. Negative for neoplasm
- B. Negative for neoplasm
- C. Negative for neoplasm
- D. Negative for neoplasm
- E. Negative for neoplasm
- F. Negative for neoplasm

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis:

LUNG CA

10/10/2010
10/10/2010
10/10/2010

10/10/2010
10/10/2010
10/10/2010

10/10/2010
10/10/2010
10/10/2010

10/10/2010
10/10/2010
10/10/2010

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh at the frozen desk is a specimen labeled "7" and consists of fibrofatty tissue with nodules that measures 1.0 x 0.5 x 0.2 cm. There are two nodules present that measure 0.5 x 0.2 x 0.2 cm, and 0.3 x 0.2 x 0.2 cm. The specimen is totally submitted for frozen section evaluation in cassette A1.

B. Received fresh at the frozen desk is a specimen labeled "R4" and consists of a single piece of adipose tissue with multiple attached nodules. The specimen measures 1.2 x 0.8 x 0.2 cm. The specimen is totally submitted for frozen section evaluation in cassette B1.

C. Received fresh at the frozen desk is a specimen labeled "4L" and consists of adipose tissue with multiple attached nodules. The specimen measures 1.2 x 0.8 x 0.3 cm. The specimen is totally submitted for frozen section evaluation in cassette C1.

D. Received fresh at the frozen desk is a specimen labeled "R2" and consists of adipose tissue with attached nodules. The specimen measures 0.9 x 0.9 x 0.2 cm. The specimen is totally submitted for frozen section evaluation in cassette D1.

E. Received fresh at the frozen desk is a specimen labeled "L2" and consists of adipose tissue with multiple attached nodules. The specimen measures 1.8 x 1.0 x 0.4 cm. The fat is removed, and the nodules are totally submitted for frozen section evaluation in cassette E1. The remainder of the adipose tissue is submitted for permanent section in cassette E2.

F. Received labeled "level 5" are three pieces of red-gray soft tissue aggregating to 2.3 x 2.0 x 0.5 cm. The specimen is totally submitted in FSF1.

G. Received fresh labeled "left upper lobe" is a lobectomy specimen of the upper lobe of the left lung weighing 285 grams (fresh), and measuring 18.5 x 11 x 4 cm. A well-circumscribed, firm, gray-white mass measuring 3.5 x 3 x 2.5 cm is present within the lung parenchyma, with a central area of scar and possible necrosis. The mass is adjacent to an irregular area of fibrosis that extends to the pleura, which is thickened with adhesions. The mass extends to 0.3 cm from the closest staple margin (inked orange). The remainder of the lung parenchyma appears unremarkable. Two possible anthracotic hilar lymph nodes are identified, measuring 0.3 cm and 1.2 cm in greatest dimension. Representative sections are submitted as follows: FSG1 frozen bronchial margin, G2 vascular margins, G3 possible lymph nodes, G4 -G5 fibrous area with thickened pleura, G6-G10 mass (G9 mass with staple line, G10 with visceral pleura), G11 unremarkable lung.

H. Received fresh labeled "level 4" are multiple irregular shaped segments of gray soft tissue resembling lymph nodes aggregating to 1.3 x 0.4 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

I. Received fresh labeled "level 7" are multiple irregular shaped segments of gray soft tissue resembling

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

lymph nodes aggregating to 1.9 x 2.3 x 0.4 cm. The specimen is totally submitted in formalin in one cassette.

J. Received fresh labeled "level 10" are multiple irregular shaped segments of gray soft tissue resembling lymph nodes aggregating to 3.7 x 2.6 x 0.4 cm. The specimen is totally submitted in formalin in three cassettes.

K. Received fresh labeled "level 11" are multiple irregular shaped segments of gray soft tissue resembling lymph nodes aggregating to 3.5 x 2.4 x 0.8 cm. The specimen is totally submitted in formalin in three cassettes.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 1af83260-7ac3-472d-98e8-21f41cf2213d (TCGA-68-7757.87FD1307-E3EB-45DA-B0EC-2E3CB95E06D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).